TCGA case TCGA-14-0736 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Emory University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cdfcf14d-ed6c-419f-88f5-e7dee96fcaf6

Demographics
Sex at birth: male; Race: black or african american; Age at index: 49 years; Vital status: Dead; Days to death: 460 days (1.3 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 49.9 years (18,219 days); Year of diagnosis: 1999; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Initial disease status: Progressive Disease; Days to treatment start: 0 days; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 58 days; Days to treatment end: 102 days; Treatment dose: 5,940 cGy; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Initial disease status: Progressive Disease; Days to treatment start: 128 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine Implant; Initial disease status: Progressive Disease; Days to treatment start: 207 days; Treatment dose: 8 Wafer.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 371 days (1.0 years); Days to treatment end: 376 days (1.0 years); Number of cycles: 1; Treatment dose: 2,000 mg; Route of administration: Oral.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 50.2 years (18,347 days); Days to diagnosis: 128 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 207 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 128 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 128 days.
- Days to follow up: 460 days (1.3 years); Disease response: With Tumor.
- Karnofsky performance status: 100; Timepoint: Prior to Adjuvant Therapy.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-14-0736-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.5; Intermediate dimension: 0.4; Shortest dimension: 0.3.
  Slide TCGA-14-0736-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent necrosis: 20; Percent monocyte infiltration: 100.
  Slide TCGA-14-0736-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent necrosis: 10; Percent monocyte infiltration: 100.
- Sample TCGA-14-0736-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-14-0736-02A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
  Slide TCGA-14-0736-02A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
- Sample TCGA-14-0736-10C: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Gliadel; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: Other (specify below).
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3: Pharmaceutical therapy drug name: Temador; Therapy regimen: Progression.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 460 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 460 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 128 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-14-0736-01A-01D-0517-01): tumor purity 0.57, ploidy 3.46, whole-genome doublings 1.
Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-14-0736-02A-01D-2002-01): tumor purity 0.46, ploidy 1.79, whole-genome doublings 0.
